Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A8OB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A8OB-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:
Med. Rec. #:
DOB:
Soc. Sec. #:
Physician(s):

Visit #:
Sex: Male
Location:

Accession #:
Service Date:
Received:
Client:

FINAL PATHOLOGIC DIAGNOSIS

*ICD O-3
Carcinoma, urothelial NOS 8120/3
Site: Bladder NOS 067.9
9/21/23/14*

- A. Ureter, left, biopsy: No tumor.
- B. Ureter, right, biopsy: No tumor.
- C. Bladder and prostate and seminal vesicles, cystoprostatectomy:
- Bladder: Invasive high grade urothelial carcinoma; see comment.
- Prostate: Focal atypical glands; see comment.
- Seminal vesicle: No tumor.
- D. Apical margin, biopsy: No tumor.
- E. Pelvic lymph nodes, right, excision: Metastatic urothelial carcinoma in one lymph node (1/3).
- F. Pelvic lymph node, left, excision: No tumor in one lymph node (0/1).
- G. Final ureter, left, biopsy: Fibromuscular and vascular tissue with no tumor.
- H. Final ureter, right, biopsy: No tumor.

COMMENT:

Bladder Tumor Synoptic Comment

1. Tumor type: Urothelial (transitional cell) carcinoma.
2. Tumor grade: High grade.
3. Tumor size: Gross appearance at least 1.9 cm in greatest diameter.
4. Extent of tumor in bladder: Invasion through muscularis propria into perivesical tissue.
5. Lymphatic/vascular invasion: None definitively identified.
6. Epithelial abnormalities in bladder: Focal areas of carcinoma in situ.

[page 2 of 3]
7. Extension of tumor into organs adjacent to bladder: No adjacent organs involved.

8. Surgical margins:

Urethral margin: Free of tumor.

Right ureter margin: Free of tumor.

Left ureter margin: Free of tumor.

Perivesical margin: Invasive tumor <0.5 mm to inked specimen margin.

9. Lymph nodes: 1 of 4 lymph nodes contain metastatic tumor; the largest metastatic deposit measures 1.2 cm in greatest dimension; there is no extranodal tumor growth.

10. Other pathologic findings in bladder: None.

11. AJCC/UICC stage: pT3aN1Mx / Stage IV.

12. Additional Comments: There is a single focus of atypical prostatic glands in the section taken as distal urethral margin on the frozen section slide FS3 but this focus is no longer present on the permanent sections. A select slide (slide FS3) was shown at the departmental , and the faculty in attendance concurred with the above diagnosis. No definitive prostatic or urothelial carcinoma is present in prostate or seminal vesicles.

In Part A and B, the tissue is best demonstrated on the original frozen section slides and no dysplasia or carcinoma is identified.

Specimen(s) Received

A: Left ureter (FS)

B: Right ureter (FS)

C: Prostate and seminal vesicles, bladder (FS)

D: Apical margin

E: Right pelvic lymph node

F: Left pelvic lymph node

G: Final left ureter

H: Final right ureter

Intraoperative Diagnosis

FS1 (A) Left ureter, biopsy: No carcinoma.

FS2 (B) Right ureter, biopsy: No carcinoma.

FS3 (C) Urethral margin, cystoprostatectomy:

1. Atypical glands, suspicious for prostate carcinoma.

2. No urothelial carcinoma.

Clinical History

The patient is a -year-old man who undergoes a transurethral resection of bladder tumor at another institution. At cystoscopy, the sessile tumor was greater than 5 cm and invading into the perivesicular fat.

Gross Description

The specimen is received fresh in eight parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "left ureter frozen section." It consists of a single round piece of soft, pink-red tissue, measuring 0.3 x 0.3 x 0.1 cm. The specimen is entirely submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1.

Part B is additionally labeled "right ureter frozen section." It consists of a single irregular piece of soft, pink-red tissue, measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted for frozen section diagnosis as FS2, with the frozen section remnant submitted in cassette B1.

Part C is additionally labeled "bladder and prostate and seminal vesicles." It consists of a bladder and attached prostate weighing 277.5 grams and measuring 16 x 13 x 4.5 cm. The external surface has

[page 3 of 3]
IIA Discrepancy		/
Metastatic Malignancy History		/
Local/Regional/Synchronous Primary Noted		/
Case is (a) (b) (c) (d) (e) (f) (g) (h) (i) (j) (k) (l) (m) (n) (o) (p) (q) (r) (s) (t) (u) (v) (w) (x) (y) (z) (aa) (ab) (ac) (ad) (ae) (af) (ag) (ah) (ai) (aj) (ak) (al) (am) (an) (ao) (ap) (aq) (ar) (as) (at) (au) (av) (aw) (ax) (ay) (az) (ba) (bb) (bc) (bd) (be) (bf) (bg) (bh) (bi) (bj) (bk) (bl) (bm) (bn) (bo) (bp) (bq) (br) (bs) (bt) (bu) (bv) (bw) (bx) (by) (bz) (ca) (cb) (cc) (cd) (ce) (cf) (cg) (ch) (ci) (cj) (ck) (cl) (cm) (cn) (co) (cp) (cq) (cr) (cs) (ct) (cu) (cv) (cw) (cx) (cy) (cz) (da) (db) (dc) (dd) (de) (df) (dg) (dh) (di) (dj) (dk) (dl) (dm) (dn) (do) (dp) (dq) (dr) (ds) (dt) (du) (dv) (dw) (dx) (dy) (dz) (ea) (eb) (ec) (ed) (ee) (ef) (eg) (eh) (ei) (ej) (ek) (el) (em) (en) (eo) (ep) (eq) (er) (es) (et) (eu) (ev) (ew) (ex) (ey) (ez) (fa) (fb) (fc) (fd) (fe) (ff) (fg) (fh) (fi) (fj) (fk) (fl) (fm) (fn) (fo) (fp) (fq) (fr) (fs) (ft) (fu) (fv) (fw) (fx) (fy) (fz) (ga) (gb) (gc) (gd) (ge) (gf) (gg) (gh) (gi) (gj) (gk) (gl) (gm) (gn) (go) (gp) (gq) (gr) (gs) (gt) (gu) (gv) (gw) (gx) (gy) (gz) (ha) (hb) (hc) (hd) (he) (hf) (hg) (hh) (hi) (hj) (hk) (hl) (hm) (hn) (ho) (hp) (hq) (hr) (hs) (ht) (hu) (hv) (hw) (hx) (hy) (hz) (ia) (ib) (ic) (id) (ie) (if) (ig) (ih) (ii) (ij) (ik) (il) (im) (in) (io) (ip) (iq) (ir) (is) (it) (iu) (iv) (iw) (ix) (iy) (iz) (ja) (jb) (jc) (jd) (je) (jf) (jg) (jh) (ji) (jj) (jk) (jl) (jm) (jn) (jo) (jp) (jq) (jr) (js) (jt) (ju) (jv) (jw) (jx) (jy) (jz) (ka) (kb) (kc) (kd) (ke) (kf) (kg) (kh) (ki) (kj) (kk) (kl) (km) (kn) (ko) (kp) (kq) (kr) (ks) (kt) (ku) (kv) (kw) (kx) (ky) (kz) (la) (lb) (lc) (ld) (le) (lf) (lg) (lh) (li) (lj) (lk) (ll) (lm) (ln) (lo) (lp) (lq) (lr) (ls) (lt) (lu) (lv) (lw) (lx) (ly) (lz) (ma) (mb) (mc) (md) (me) (mf) (mg) (mh) (mi) (mj) (mk) (ml) (mm) (mn) (mo) (mp) (mq) (mr) (ms) (mt) (mu) (mv) (mw) (mx) (my) (mz) (na) (nb) (nc) (nd) (ne) (nf) (ng) (nh) (ni) (nj) (nk) (nl) (nm) (nn) (no) (np) (nq) (nr) (ns) (nt) (nu) (nv) (nw) (nx) (ny) (nz) (oa) (ob) (oc) (od) (oe) (of) (og) (oh) (oi) (oj) (ok) (ol) (om) (on) (oo) (op) (oq) (or) (os) (ot) (ou) (ov) (ow) (ox) (oy) (oz) (pa) (pb) (pc) (pd) (pe) (pf) (pg) (ph) (pi) (pj) (pk) (pl) (pm) (pn) (po) (pp) (pq) (pr) (ps) (pt) (pu) (pv) (pw) (px) (py) (pz) (qa) (qb) (qc) (qd) (qe) (qf) (qg) (qh) (qi) (qj) (qk) (ql) (qm) (qn) (qo) (qp) (qq) (qr) (qs) (qt) (qu) (qv) (qw) (qx) (qy) (qz) (ra) (rb) (rc) (rd) (re) (rf) (rg) (rh) (ri) (rj) (rk) (rl) (rm) (rn) (ro) (rp) (rq) (rr) (rs) (rt) (ru) (rv) (rw) (rx) (ry) (rz) (sa) (sb) (sc) (sd) (se) (sf) (sg) (sh) (si) (sj) (sk) (sl) (sm) (sn) (so) (sp) (sq) (sr) (ss) (st) (su) (sv) (sw) (sx) (sy) (sz) (ta) (tb) (tc) (td) (te) (tf) (tg) (th) (ti) (tj) (tk) (tl) (tm) (tn) (to) (tp) (tq) (tr) (ts) (tt) (tu) (tv) (tw) (tx) (ty) (tz) (ua) (ub) (uc) (ud) (ue) (uf) (ug) (uh) (ui) (uj) (uk) (ul) (um) (un) (uo) (up) (uq) (ur) (us) (ut) (uu) (uv) (uw) (ux) (uy) (uz) (va) (vb) (vc) (vd) (ve) (vf) (vg) (vh) (vi) (vj) (vk) (vl) (vm) (vn) (vo) (vp) (vq) (vr) (vs) (vt) (vu) (vv) (vw) (vx) (vy) (vz) (wa) (wb) (wc) (wd) (we) (wf) (wg) (wh) (wi) (wj) (wk) (wl) (wm) (wn) (wo) (wp) (wq) (wr) (ws) (wt) (wu) (wv) (ww) (wx) (wy) (wz) (xa) (xb) (xc) (xd) (xe) (xf) (xg) (xh) (xi) (xj) (xk) (xl) (xm) (xn) (xo) (xp) (xq) (xr) (xs) (xt) (xu) (xv) (xw) (xx) (xy) (xz) (ya) (yb) (yc) (yd) (ye) (yf) (yg) (yh) (yi) (yj) (yk) (yl) (ym) (yn) (yo) (yp) (yq) (yr) (ys) (yt) (yu) (yv) (yw) (yx) (yy) (yz) (za) (zb) (zc) (zd) (ze) (zf) (zg) (zh) (zi) (zj) (zk) (zl) (zm) (zn) (zo) (zp) (zq) (zr) (zs) (zt) (zu) (zv) (zw) (zx) (zy) (zz)		

Source: NCI Genomic Data Commons file ceeb5e93-954f-4f28-8a75-4bdd143d8fb7 (TCGA-UY-A8OB.1D6D35DC-D4B8-4186-9EA4-97F53314D01B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).